Somatic mutation profile of tumor specimen TCGA-17-Z059-01A (aliquot TCGA-17-Z059-01A-01W-0747-08) from TCGA case TCGA-17-Z059, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8726c740-3208-42f5-82b8-fa292a1f2846.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z059-11A (Solid Tissue Normal), aliquot TCGA-17-Z059-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c77feefa-358b-4a23-abeb-91d3f743f19f

The open-access MAF lists 164 somatic variants for this specimen: 128 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 32, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 2, RNA 2, Intron 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS6 | c.2719del p.D907Ifs*38 | Frame Shift Del (DEL) | VAF 65/314 reads (21%) | catalogued as COSV58683162; called by mutect2, pindel, varscan2
- ARID1A | c.4994-2A>G p.X1665_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100253620, COSV61377871; called by muse, mutect2, varscan2
- ARMC5 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs574169297, COSV99192645; called by muse, mutect2, varscan2
- ASXL3 | c.5043G>T p.M1681I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV52466476; called by muse, mutect2, varscan2
- C2orf78 | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs368168109, COSV68518427; called by muse, mutect2, varscan2
- C2orf78 | c.2651G>C p.R884T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101280906, COSV68519290; called by muse, mutect2, varscan2
- CSMD2 | c.1863C>A p.N621K | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs138506777; called by muse, mutect2, varscan2
- DNAH2 | c.12809G>T p.R4270L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as rs575354824; called by muse, mutect2, varscan2
- DNAH8 | c.13004C>T p.T4335M | Missense Mutation (SNP) | VAF 220/995 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs375993164; called by muse, varscan2
- DOK1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs761349293; called by muse, mutect2, varscan2
- DSC2 | c.274A>G p.R92G | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV51862370; called by muse, mutect2, varscan2
- EHHADH | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV51628611; called by muse, mutect2, varscan2
- ERICH3 | c.1291G>C p.V431L | Missense Mutation (SNP) | VAF 90/426 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58604164; called by muse, mutect2, varscan2
- FAM47C | c.2910dup p.D971Rfs*4 | Frame Shift Ins (INS) | VAF 20/88 reads (23%) | catalogued as rs782417722; called by pindel, varscan2
- HAVCR1 | c.443C>A p.T148N | Missense Mutation (SNP) | VAF 190/813 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.81); catalogued as COSV59399860, COSV99042852; called by muse, mutect2, varscan2
- HEMGN | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as COSV99412262; called by muse, mutect2, varscan2
- KAT2A | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs782687964; called by muse, mutect2, varscan2
- KLHL1 | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64781364; called by muse, mutect2, varscan2
- KLK5 | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.039); catalogued as COSV60450787; called by muse, mutect2, varscan2
- KPNA4 | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs1317065006; called by muse, mutect2, varscan2
- LCT | c.3434G>A p.R1145Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762161026; called by muse, mutect2, varscan2
- MAD2L1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs1259049816; called by muse, mutect2, varscan2
- MDGA2 | c.2198C>A p.A733E (on ENST00000399232 / NM_001113498.2; = p.A435E on NM_182830.4) | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100636535; called by muse, mutect2, varscan2
- MMS19 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59135687; called by muse, mutect2, varscan2
- MTCH1 | c.1142C>T p.S381L (on ENST00000373627 / NM_001271641.1; = p.S364L on NM_014341.2) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1451038510; called by muse, mutect2, varscan2
- MYH6 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as rs759408374, COSV62447730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1L | c.1455C>G p.S485R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.201); catalogued as rs779689003, COSV67724245; called by muse, mutect2, varscan2
- NMS | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1389145001; called by muse, mutect2, varscan2
- OR10Z1 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV63524679; called by mutect2, varscan2
- OR7E24 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV101509682; called by muse, mutect2, varscan2
- OR8J1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs181729175, COSV57317950; called by muse, mutect2, varscan2
- OSBPL7 | c.1145G>C p.R382P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV50114019; called by muse, mutect2, varscan2
- PCDH15 | c.5083G>A p.E1695K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV57315355; called by muse, mutect2
- PDZD8 | c.2938A>G p.S980G | Missense Mutation (SNP) | VAF 221/917 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV53692404; called by muse, mutect2, varscan2
- PEG3 | c.315G>T p.W105C | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1227589813; called by muse, mutect2, varscan2
- PEX5L | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1446887075; called by muse, mutect2, varscan2
- PIP4P2 | c.630+1G>C p.X210_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as rs1261285168; called by muse, mutect2, varscan2
- RADIL | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as rs760645833; called by muse, varscan2
- RESF1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as COSV57023642; called by muse, mutect2, varscan2
- THSD7A | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986010893, COSV69855313; called by muse, mutect2, varscan2
- TNN | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.155); catalogued as COSV53432389; called by muse, mutect2, varscan2
- WDR49 | c.631A>T p.S211C (on ENST00000308378 / NM_001366158.1; = p.S552C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/436 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs966691614; called by muse, varscan2
- ZC3H7B | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs766038481, COSV100687342; called by muse, mutect2, varscan2
- ZNF676 | c.1541G>A p.C514Y (on ENST00000650058; = p.C482Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763929340; called by muse, mutect2, varscan2
- ZP4 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs147732809; called by muse, varscan2
- ABCB5 | c.1102A>T p.S368C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ACBD6 | c.716A>T p.D239V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ACRV1 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACSL6 | c.970C>G p.H324D (on ENST00000379240; = p.H349D on NM_001009185.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ALS2CL | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- AQP10 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASXL3 | c.5044G>T p.D1682Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ATAD2 | c.1577C>G p.S526* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- ATP4A | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CALB2 | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCT6B | c.922C>G p.H308D | Missense Mutation (SNP) | VAF 6/166 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- CD27 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 71/294 reads (24%) | called by muse, mutect2, varscan2
- CFAP65 | c.3944T>A p.L1315Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.281); called by muse, mutect2
- CFHR5 | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CLEC4M | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 33/151 reads (22%) | called by muse, mutect2, varscan2
- COL6A6 | c.4618G>T p.G1540C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CYB5R4 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CYP2C18 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 151/680 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- DCC | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- DNAJC6 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 178/774 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, varscan2
- DSC2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- EHBP1 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2
- ELMO2 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2
- EPHA6 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FLNA | c.4159G>T p.G1387C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLT1 | c.3931C>A p.H1311N | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA2 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSDMA | c.603C>G p.C201W | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HLA-DOA | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- HS3ST6 | c.721del p.L241Cfs*29 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- IGSF10 | c.3841G>T p.G1281* | Nonsense Mutation (SNP) | VAF 60/270 reads (22%) | called by muse, mutect2, varscan2
- IL3RA | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF1A | c.3194A>T p.E1065V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- KIF1B | c.3175G>A p.E1059K (on ENST00000377086 / NM_001365952.1; = p.E1013K on NM_015074.3) | Missense Mutation (SNP) | VAF 104/519 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- KIF2B | c.1682C>A p.A561E | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT14 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- KTN1 | c.1352T>A p.L451Q | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIG1 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4C | c.1189G>C p.G397R | Missense Mutation (SNP) | VAF 116/542 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARK3 | c.1411A>T p.M471L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- METTL25 | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPAP1 | c.1885C>A p.H629N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OR10G2 | c.911T>A p.L304Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OR2T27 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR8J3 | c.557C>A p.A186E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PCDH17 | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PCDHA10 | c.1072G>T p.V358L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PCDHA6 | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PCDHGB1 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZRN3 | c.2637C>A p.H879Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PEX13 | c.558G>C p.R186S | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKD1L1 | c.7897C>G p.Q2633E | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.042); called by muse, mutect2
- PLCL2 | c.2326G>T p.G776C (on ENST00000615277 / NM_001144382.2; = p.G650C on NM_015184.5) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPT2 | c.462del p.T155Pfs*43 | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- RAB28 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPGEF4 | c.2424G>C p.K808N | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2
- RNF20 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RSPH6A | c.2048T>A p.V683E | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RYR2 | c.13093G>C p.D4365H | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SCN2A | c.1754A>G p.K585R | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SELE | c.647C>A p.P216Q | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHCBP1 | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SLC35G2 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLIT2 | c.10G>T p.V4F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SMC6 | c.2690A>T p.E897V | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SNTG1 | c.185G>T p.R62I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SQOR | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TAS2R40 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TBPL2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TCF7L1 | c.1272G>C p.K424N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TCTN2 | c.2013G>T p.K671N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TDO2 | c.1151C>G p.T384S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFDP3 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- TMTC1 | c.2170G>T p.A724S (on ENST00000539277 / NM_001193451.2; = p.A616S on NM_175861.3) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMTC3 | c.2128C>T p.L710F | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TTF1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TTN | c.60254A>C p.E20085A (on ENST00000591111; = p.E12661A on NM_003319.4) | Missense Mutation (SNP) | VAF 8/247 reads (3%) | PolyPhen probably damaging (0.995); called by muse, mutect2
- TTN | c.43315G>T p.D14439Y (on ENST00000591111; = p.D7015Y on NM_003319.4) | Missense Mutation (SNP) | VAF 13/372 reads (3%) | PolyPhen possibly damaging (0.502); called by muse, mutect2
- XIRP1 | c.1350G>C p.L450F | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFR | c.2476G>C p.E826Q | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.272); called by muse, mutect2
- ZNF256 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- ZNF292 | c.4278dup p.L1427Sfs*23 | Frame Shift Ins (INS) | VAF 26/254 reads (10%) | called by pindel, varscan2
- ZNF292 | c.4282T>G p.S1428A | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, varscan2
- ALDH1A3 | c.549C>A p.P183= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.354C>T p.T118= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- APOO | c.204A>G p.R68= | Silent (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- ATP1A2 | c.2290C>T p.L764= | Silent (SNP) | VAF 54/356 reads (15%) | called by muse, mutect2, varscan2
- ATP5F1B | c.195G>T p.A65= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- CDH9 | c.783C>T p.V261= | Silent (SNP) | VAF 104/445 reads (23%) | called by muse, mutect2, varscan2
- COL7A1 | c.8259G>T p.V2753= | Silent (SNP) | VAF 48/198 reads (24%) | called by muse, mutect2, varscan2
- CSF1R | c.285C>A p.A95= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- DCBLD2 | c.2046C>T p.I682= | Silent (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- EXTL3 | c.801G>T p.R267= | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- F13B | c.1866A>T p.P622= | Silent (SNP) | VAF 27/209 reads (13%) | called by muse, mutect2, varscan2
- GABRB3 | c.84C>A p.I28= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs771906844, COSV100165300; called by mutect2, varscan2
- HEATR1 | c.495A>T p.P165= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- ITPR3 | c.501C>T p.F167= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs370534623; called by muse, mutect2, varscan2
- JAK3 | c.219G>T p.L73= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- MATR3 | c.858G>A p.P286= | Silent (SNP) | VAF 114/494 reads (23%) | catalogued as COSV63078113; called by muse, mutect2, varscan2
- MPL | c.792C>A p.S264= | Silent (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- OR2T27 | c.273C>A p.A91= | Silent (SNP) | VAF 24/62 reads (39%) | called by mutect2, varscan2
- OR2W3 | c.159C>A p.P53= | Silent (SNP) | VAF 168/571 reads (29%) | called by muse, mutect2, varscan2
- OR6Y1 | c.735C>A p.T245= | Silent (SNP) | VAF 91/526 reads (17%) | catalogued as COSV56930662; called by muse, mutect2, varscan2
- P4HA1 | c.570C>T p.A190= | Silent (SNP) | VAF 24/253 reads (9%) | called by muse, mutect2
- PCDHB2 | c.1641G>T p.A547= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV50623985; called by muse, mutect2, varscan2
- RELN | c.2427C>A p.L809= | Silent (SNP) | VAF 54/213 reads (25%) | catalogued as COSV58999286; called by muse, mutect2, varscan2
- RGL1 | c.1258C>T p.L420= (on ENST00000360851 / NM_001297672.2; = p.L455= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 90/410 reads (22%) | called by muse, mutect2, varscan2
- SERPINE1 | c.288C>A p.P96= | Silent (SNP) | VAF 74/356 reads (21%) | catalogued as COSV56171762; called by muse, mutect2, varscan2
- SIPA1L1 | c.804G>A p.Q268= | Silent (SNP) | VAF 36/414 reads (9%) | called by muse, mutect2
- SLC4A1 | c.1410G>A p.V470= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- ST18 | c.969C>A p.T323= | Silent (SNP) | VAF 25/195 reads (13%) | catalogued as COSV52494702; called by muse, mutect2, varscan2
- STAT3 | c.1581A>T p.T527= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.27330G>A p.K9110= (on ENST00000591111; = p.K8183= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- WNT10B | c.1095T>C p.H365= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- ZKSCAN8 | c.1419G>C p.R473= | Silent (SNP) | VAF 36/142 reads (25%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-17168G>T | Intron (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- NBPF25P | n.1011C>T | RNA (SNP) | VAF 245/1525 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10303+1346G>A | Intron (SNP) | VAF 51/233 reads (22%) | called by muse, mutect2, varscan2
- VN1R10P | n.651G>A | RNA (SNP) | VAF 76/410 reads (19%) | called by muse, varscan2
